Somatic mutation profile of tumor specimen TCGA-44-6779-01A (aliquot TCGA-44-6779-01A-11D-1855-08) from TCGA case TCGA-44-6779, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 50.6 years (18,469 days).
Specimen TCGA-44-6779-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 564349f2-920c-4b4e-98e1-d179bceac096.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-6779-11A (Solid Tissue Normal), aliquot TCGA-44-6779-11A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cd60a72-9deb-4866-8592-01c27f2e83ea

The open-access MAF lists 106 somatic variants for this specimen: 78 protein-altering or splice-affecting, 23 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 23, Nonsense Mutation 4, Frame Shift Del 4, Intron 2, RNA 2, In Frame Ins 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs180177239, CM993607, COSV56754178; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.1837C>T p.R613* | Nonsense Mutation (SNP) | VAF 12/73 reads (16%) | catalogued as rs398123585, CM065453, COSV57667669; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.394A>G p.K132E | Missense Mutation (SNP) | VAF 9/23 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747342068, CM086989, CM973641, COSV52689323, COSV52708494, COSV52979406, COSV53353999; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABHD12B | c.619G>C p.G207R (on ENST00000337334 / NM_001206673.2; = p.G130R on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.2); catalogued as COSV100485861, COSV100485879; called by muse, mutect2, varscan2
- AFF2 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as COSV54009461; called by muse, mutect2, varscan2
- AL441992.2 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs551408131, COSV56917033; called by muse, mutect2, varscan2
- AOX1 | c.669G>T p.M223I | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV65984420; called by muse, mutect2, varscan2
- ARHGAP11A | c.234C>G p.D78E | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64381718; called by muse, mutect2, varscan2
- ARL5A | c.356G>C p.G119A | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as COSV99706829; called by muse, mutect2
- ATP7A | c.3155G>T p.G1052V | Missense Mutation (SNP) | VAF 95/302 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100430994, COSV58455059; called by muse, mutect2, varscan2
- CCDC113 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs780838577, COSV54685884, COSV54687144; called by muse, mutect2, varscan2
- CHST12 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1254761720, COSV99324353; called by mutect2, varscan2
- COL13A1 | c.2116G>A p.E706K (on ENST00000398978 / NM_001130103.2; = p.E634K on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1139030, COSV62568283; called by muse, mutect2, varscan2
- CSMD3 | c.2512G>T p.G838* (on ENST00000297405 / NM_001363185.1; = p.G734* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 29/104 reads (28%) | catalogued as COSV52334618; called by muse, mutect2, varscan2
- CSPG4 | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs775593500, COSV57901568; called by muse, mutect2, varscan2
- DBT | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.074); catalogued as COSV64495493, COSV64496405; called by muse, mutect2, varscan2
- DIP2B | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs900549141, COSV56593046; called by muse, mutect2, varscan2
- DYTN | c.549C>A p.F183L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65971005; called by muse, mutect2
- ELAPOR1 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV64047336; called by muse, mutect2, varscan2
- EPCAM | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as rs762151416, COSV55394795; called by muse, mutect2, varscan2
- EPHA5 | c.2771A>C p.K924T | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as COSV56636729, COSV56652018; called by muse, mutect2, varscan2
- EXT2 | c.660G>T p.W220C (on ENST00000343631; = p.W253C on NM_000401.3) | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV59155806; called by muse, mutect2, varscan2
- FIGN | c.2256C>A p.N752K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV60763428, COSV60772167; called by muse, mutect2, varscan2
- GABRR1 | c.1161C>A p.S387R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV65620898; called by muse, mutect2
- GCA | c.224G>C p.R75T | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as COSV52026953; called by muse, mutect2, varscan2
- GPR137B | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 64/227 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as rs759943159, COSV63991802; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.6+1G>T p.X2_splice | Splice Site (SNP) | VAF 21/161 reads (13%) | catalogued as COSV100523028; called by muse, mutect2, varscan2
- JAG2 | c.3418C>T p.R1140W | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs772593683, COSV59313639; called by muse, mutect2, varscan2
- JAML | c.355C>T p.R119C (on ENST00000356289 / NM_001098526.2; = p.R109C on NM_153206.3) | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs762860196, COSV52629872; called by muse, mutect2, varscan2
- KCNK10 | c.607G>C p.G203R | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56640391, COSV56653405; called by muse, mutect2, varscan2
- KCNK2 | c.497G>T p.R166L (on ENST00000444842 / NM_001017425.3; = p.R151L on NM_014217.4) | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV67210922, COSV67211121; called by muse, mutect2, varscan2
- KCTD2 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761691109, COSV56903521; called by muse, mutect2
- KEAP1 | c.425C>T p.T142M | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50430694; called by muse, mutect2, varscan2
- KIAA1217 | c.3136C>A p.P1046T | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750460394, COSV56811962; called by muse, mutect2, varscan2
- KLK7 | c.304C>G p.P102A | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100304514; called by muse, mutect2, varscan2
- LMBRD1 | c.1099G>A p.G367R (on ENST00000649011; = p.G345R on NM_018368.4) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV65300319; called by muse, mutect2, varscan2
- LRP1B | c.2946C>A p.S982R | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.442); catalogued as COSV67279831; called by muse, mutect2, varscan2
- LRRC66 | c.2122G>T p.G708W | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100603121; called by muse, mutect2, varscan2
- LRRC66 | c.2121G>T p.E707D | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100603122; called by muse, mutect2, varscan2
- LSM14A | c.1229G>A p.R410K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); catalogued as COSV101471762; called by muse, mutect2, varscan2
- MAGEB6 | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100983635, COSV66873231; called by muse, mutect2, varscan2
- MED12 | c.4762G>A p.V1588M | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs767396596, COSV61333102; called by muse, mutect2, varscan2
- NPLOC4 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs776098226, COSV58620223; called by muse, mutect2, varscan2
- NUDT1 | c.367G>A p.E123K (on ENST00000397048 / NM_198952.1; = p.E100K on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs115556911, COSV56130572; called by muse, mutect2, varscan2
- OR2AG2 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.828); catalogued as COSV58456367; called by muse, mutect2, varscan2
- PATJ | c.2981A>G p.Q994R | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV57173003; called by muse, mutect2, varscan2
- PCDHB7 | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as rs201836983, COSV50764975; called by muse, mutect2, varscan2
- PGR | c.1901T>G p.L634R | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54811613; called by muse, mutect2, varscan2
- PKD1L1 | c.4729G>T p.V1577L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.369); catalogued as COSV56979708; called by muse, mutect2, varscan2
- PLEKHA3 | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as rs770400483, COSV52296867; called by muse, mutect2, varscan2
- PLXNA3 | c.4084G>A p.G1362S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.48); PolyPhen probably damaging (1); catalogued as rs1157314985, COSV63755948; called by muse, mutect2, varscan2
- POM121L12 | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1358921097, COSV68693630; called by muse, mutect2, varscan2
- PPRC1 | c.4028C>T p.P1343L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374891266, COSV99531933; called by muse, mutect2, varscan2
- PRB3 | c.661C>A p.R221S (on ENST00000381842; = p.R263S on NM_006249.5) | Missense Mutation (SNP) | VAF 115/468 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV99686128; called by muse, mutect2, varscan2
- PRDM2 | c.5060G>A p.R1687Q | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); catalogued as rs746354799, COSV52449967; called by muse, varscan2
- RAB3GAP2 | c.2466G>T p.Q822H | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV62787533; called by muse, mutect2, varscan2
- RBM44 | c.62T>C p.L21P (on ENST00000611254; = p.L655P on NM_001080504.2) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57633675; called by muse, mutect2, varscan2
- RP1L1 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as rs374588944, COSV66760935; called by muse, varscan2
- RSL1D1 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 20/566 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1192763415, COSV63078597; called by muse, mutect2
- SLC41A1 | c.1496A>T p.H499L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.065); catalogued as COSV65651712; called by muse, mutect2
- SLITRK5 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61526843; called by muse, mutect2, varscan2
- SNX24 | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV54456695; called by muse, mutect2, varscan2
- STRC | c.5110C>T p.Q1704* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as COSV55853924; called by muse, mutect2, varscan2
- TCF4 | c.1418C>A p.P473Q | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as COSV61907150; called by muse, mutect2, varscan2
- TH | c.668C>A p.P223Q (on ENST00000381178 / NM_199292.3; = p.P192Q on NM_000360.4) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760346235, COSV60768817; called by muse, mutect2, varscan2
- TSHZ3 | c.1697C>A p.S566* | Nonsense Mutation (SNP) | VAF 40/103 reads (39%) | catalogued as COSV53684223; called by muse, mutect2, varscan2
- TTN | c.73796G>T p.C24599F (on ENST00000591111; = p.C17175F on NM_003319.4) | Missense Mutation (SNP) | VAF 61/227 reads (27%) | PolyPhen benign (0); catalogued as COSV60382453; called by muse, mutect2, varscan2
- UBR4 | c.9848C>T p.A3283V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as rs867563278, COSV64400747; called by muse, mutect2
- UNC13C | c.5228G>A p.S1743N | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV52929335; called by muse, mutect2, varscan2
- USP7 | c.2434A>T p.T812S | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV61217827; called by muse, mutect2, varscan2
- ZBTB24 | c.914A>G p.Y305C | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.063); catalogued as COSV57784007; called by muse, mutect2, varscan2
- ZNF254 | c.1634C>G p.P545R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV61645115; called by muse, mutect2, varscan2
- ZNF521 | c.3421T>A p.S1141T | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.87); catalogued as COSV100833551; called by muse, mutect2, varscan2
- ARMCX3 | c.249del p.T84Lfs*60 | Frame Shift Del (DEL) | VAF 22/168 reads (13%) | called by mutect2, pindel*, varscan2
- PTPRT | c.867del p.T290Rfs*33 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel, varscan2
- RIT1 | c.219_227dup p.L74_T76dup | In Frame Ins (INS) | VAF 19/70 reads (27%) | called by mutect2, varscan2
- SLITRK5 | c.657del p.L220Sfs*24 | Frame Shift Del (DEL) | VAF 30/97 reads (31%) | called by mutect2, pindel, varscan2
- ZDHHC13 | c.1233+1del | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- ACTR3B | c.1071G>A p.R357= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV55454362; called by muse, mutect2
- AL031777.2 | c.270C>T p.N90= | Silent (SNP) | VAF 27/170 reads (16%) | catalogued as COSV100587297, COSV61912297; called by muse, mutect2, varscan2
- AR | c.1719A>T p.G573= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as COSV65964502; called by muse, mutect2, varscan2
- BOD1L1 | c.3861G>A p.V1287= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV50078185; called by muse, mutect2, varscan2
- BRINP3 | c.1395C>A p.T465= | Silent (SNP) | VAF 55/167 reads (33%) | catalogued as COSV66542837, COSV66543497; called by muse, mutect2, varscan2
- CCL8 | c.33G>T p.L11= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV67014239; called by muse, mutect2, varscan2
- CD37 | c.831C>A p.L277= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV60544791, COSV60545361; called by muse, mutect2, varscan2
- DDO | c.897T>A p.P299= (on ENST00000368924 / NM_001368172.1; = p.P240= on NM_004032.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV64470721; called by muse, mutect2, varscan2
- DIDO1 | c.882C>T p.G294= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs541453651, COSV56634492; called by muse, mutect2, varscan2
- FOXB1 | c.825G>T p.A275= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV101249961; called by mutect2, varscan2
- GPRASP2 | c.75G>A p.G25= | Silent (SNP) | VAF 46/151 reads (30%) | catalogued as COSV59991788, COSV59992521; called by muse, mutect2, varscan2
- IGLV3-10 | c.285G>T p.G95= | Silent (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- KCNA6 | c.1257A>T p.T419= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as COSV54978306; called by muse, mutect2, varscan2
- NUP88 | c.507C>T p.T169= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV56708208; called by muse, mutect2, varscan2
- OR10P1 | c.528G>T p.P176= | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as COSV100548223; called by muse, mutect2, varscan2
- PARD6B | c.549A>G p.P183= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV65405349; called by muse, mutect2, varscan2
- REC114 | c.240G>A p.Q80= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV58524937; called by muse, mutect2, varscan2
- ROBO4 | c.2493C>T p.I831= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as rs775378391, COSV60628364; called by muse, mutect2, varscan2
- SLITRK2 | c.493C>T p.L165= | Silent (SNP) | VAF 47/208 reads (23%) | catalogued as COSV59429368; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2181G>T p.R727= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV59139137; called by muse, mutect2, varscan2
- THNSL2 | c.1332G>T p.L444= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV59085139; called by muse, mutect2
- TPCN1 | c.1338C>T p.F446= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV59233328; called by muse, varscan2
- ZNF521 | c.3420C>T p.C1140= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV64126565, COSV64130287; called by muse, mutect2, varscan2
- IGLL5 | chr22:22901031 T>G | 3'Flank (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85625A>T | Intron (SNP) | VAF 15/149 reads (10%) | catalogued as COSV72282470; called by muse, mutect2
- MIR891A | n.73C>T | RNA (SNP) | VAF 24/86 reads (28%) | called by muse, mutect2, varscan2
- SNORD115-38 | n.82C>T | RNA (SNP) | VAF 47/406 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.10360+3250A>T | Intron (SNP) | VAF 22/69 reads (32%) | catalogued as COSV60382483; called by muse, mutect2, varscan2
